Somatic mutation profile of tumor specimen TCGA-IB-A7LX-01A (aliquot TCGA-IB-A7LX-01A-12D-A36O-08) from TCGA case TCGA-IB-A7LX, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.2 years (20,898 days).
Specimen TCGA-IB-A7LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 018b7b50-3a70-4c84-b0bd-5b3c2f03d5c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A7LX-10A (Blood Derived Normal), aliquot TCGA-IB-A7LX-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/006514bc-9d7b-4367-93aa-c2def6f37711

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, RNA 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 255/500 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 80/324 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs776846119, COSV59205460, COSV59217320; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4007G>C p.R1336T | Missense Mutation (SNP) | VAF 40/760 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54461766, COSV99716284; called by muse, mutect2
- ANKRD24 | c.3010C>T p.R1004C | Missense Mutation (SNP) | VAF 131/719 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1337562891, COSV53677013; called by muse, mutect2, varscan2
- BLOC1S3 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs760982368, COSV99135258; called by muse, varscan2
- CACNG2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 121/475 reads (25%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.448); catalogued as COSV100268329; called by muse, mutect2, varscan2
- CPNE4 | c.969C>G p.N323K | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as COSV101456539; called by muse, mutect2, varscan2
- DNAH6 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 185/468 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs896640864, COSV99403955; called by muse, mutect2, varscan2
- DNHD1 | c.14081G>A p.S4694N | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99599187; called by muse, mutect2, varscan2
- DYNC1I1 | c.1355T>A p.V452D | Missense Mutation (SNP) | VAF 120/1394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100267283; called by muse, mutect2
- EMSY | c.3649G>A p.V1217I | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100595203, COSV58267183; called by muse, mutect2
- ERICH6 | c.1304A>C p.K435T | Missense Mutation (SNP) | VAF 61/477 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99901256; called by muse, mutect2, varscan2
- GPR158 | c.1335+1G>T p.X445_splice | Splice Site (SNP) | VAF 46/356 reads (13%) | catalogued as COSV100892552; called by muse, mutect2, varscan2
- JPH1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1294087636, COSV100646338; called by muse, mutect2
- KRT28 | c.1231A>T p.S411C | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs1479544242, COSV100137307; called by muse, mutect2, varscan2
- MAP3K5 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); catalogued as rs1477037366, COSV100752276, COSV62886716; called by muse, mutect2, varscan2
- MYOT | c.938T>A p.V313D | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99524659; called by muse, mutect2, varscan2
- OR4C15 | c.868C>A p.L290I (on ENST00000314644; = p.L236I on NM_001001920.2) | Missense Mutation (SNP) | VAF 226/544 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV100115274; called by muse, mutect2
- PREX2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866864487, COSV55780007; called by muse, mutect2, varscan2
- SDCCAG8 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV100653652; called by muse, mutect2, varscan2
- SF3B1 | c.2528A>G p.K843R | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV100133547; called by muse, mutect2, varscan2
- TMPRSS11D | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as COSV99384362; called by muse, mutect2, varscan2
- ZNF99 | c.1721T>G p.F574C | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101233611; called by muse, mutect2, varscan2
- BDP1 | c.77_95del p.N26Sfs*120 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- PRC1 | c.207dup p.S70Ifs*17 | Frame Shift Ins (INS) | VAF 396/1252 reads (32%) | called by mutect2, pindel, varscan2
- AKAP6 | c.4467C>T p.S1489= | Silent (SNP) | VAF 88/285 reads (31%) | catalogued as rs371708448; called by muse, mutect2, varscan2
- ANXA8 | c.279G>A p.P93= | Silent (SNP) | VAF 423/1864 reads (23%) | catalogued as rs1383554593; called by muse, mutect2, varscan2
- BATF | c.48T>G p.P16= | Silent (SNP) | VAF 91/278 reads (33%) | catalogued as COSV99708639; called by muse, mutect2, varscan2
- CHST10 | c.669A>G p.R223= | Silent (SNP) | VAF 70/578 reads (12%) | catalogued as COSV99958563; called by muse, mutect2, varscan2
- DISP3 | c.810C>T p.H270= | Silent (SNP) | VAF 51/76 reads (67%) | catalogued as COSV99606931; called by muse, mutect2, varscan2
- FCGBP | c.642C>T p.V214= | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as rs1471558730; called by muse, mutect2
- LAMB4 | c.1173G>A p.A391= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs768213293, COSV99222175; called by muse, mutect2, varscan2
- OR4C15 | c.867T>A p.A289= (on ENST00000314644; = p.A235= on NM_001001920.2) | Silent (SNP) | VAF 226/545 reads (41%) | catalogued as COSV100115272; called by muse, mutect2
- RTKN | c.1149C>T p.I383= (on ENST00000272430 / NM_001015055.2; = p.I370= on NM_033046.2) | Silent (SNP) | VAF 176/829 reads (21%) | catalogued as rs1162184294, COSV99269190; called by muse, mutect2, varscan2
- SPAG17 | c.2406G>A p.K802= | Silent (SNP) | VAF 177/319 reads (55%) | catalogued as rs1485063399, COSV100307380, COSV60464182; called by muse, mutect2, varscan2
- TEP1 | c.6900A>G p.Q2300= | Silent (SNP) | VAF 95/287 reads (33%) | catalogued as rs776756458, COSV99401314; called by muse, mutect2, varscan2
- ZNF761 | c.1557G>A p.E519= | Silent (SNP) | VAF 15/451 reads (3%) | catalogued as COSV100483193; called by muse, mutect2
- OR2W5 | n.1219A>T | RNA (SNP) | VAF 134/397 reads (34%) | called by muse, mutect2, varscan2
